CPTAC case C3N-05135 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/324bf8cd-d84f-4b9e-87ff-4dc73c7cdc0c

Demographics
Sex at birth: male; Race: asian; Year of birth: 1986; Vital status: Dead; Days to death: 323 days; Year of death: 2019; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 32.2 years (11,750 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 323 days; Progression or recurrence: no; Days to last follow up: 254 days.
   Pathology details: Greatest tumor dimension: 2.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 254 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 254 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 254 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 70 kg; Height: 170 cm; BMI: 24.22.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 1; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-05135-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 128 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-05135-21: Section location: Frontal Lobe; Percent tumor nuclei: 60; Percent necrosis: 30.
- Sample C3N-05135-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
